Somatic mutation profile of tumor specimen TCGA-IQ-A61J-01A (aliquot TCGA-IQ-A61J-01A-11D-A30E-08) from TCGA case TCGA-IQ-A61J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 54.5 years (19,913 days).
Specimen TCGA-IQ-A61J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58cd4513-b147-4012-b65a-c903fe05979b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IQ-A61J-10A (Blood Derived Normal), aliquot TCGA-IQ-A61J-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/500bf6fe-1419-46b9-a28e-7bcddc80d2fa

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, In Frame Del 3, Nonsense Mutation 3, Splice Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 44/120 reads (37%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ALPK2 | c.3248C>A p.P1083Q | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100864955; called by muse, mutect2, varscan2
- C6orf118 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463896344, COSV100025342; called by muse, mutect2, varscan2
- CACNA1H | c.6927G>T p.E2309D | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99327198; called by muse, mutect2, varscan2
- CARD11 | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as rs368574818; called by muse, mutect2, varscan2
- DARS2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs745810469, COSV53406909; called by muse, mutect2, varscan2
- DNAH8 | c.6445G>A p.G2149R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549318995, COSV100547539; called by muse, mutect2, varscan2
- KIR3DL2 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.946); catalogued as COSV99552442; called by muse, mutect2, varscan2
- LAMC3 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs777086759, COSV63090346; called by muse, mutect2, varscan2
- METTL22 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs368070440, COSV50837541; called by muse, mutect2, varscan2
- MMP20 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV52778890; called by muse, mutect2, varscan2
- MYH2 | c.4473G>C p.K1491N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55448844, COSV99821248; called by muse, mutect2
- NEB | c.7667G>A p.R2556H | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764471883, COSV51458146; called by muse, mutect2, varscan2
- NTNG1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100903913; called by muse, mutect2, varscan2
- PCDH9 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | catalogued as COSV100118849, COSV100124531; called by muse, mutect2, varscan2
- PCDHGB7 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs777772131, COSV99549903; called by muse, mutect2, varscan2
- PRKAR1B | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs774763564, COSV100816918; called by muse, mutect2, varscan2
- RELT | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV99293175; called by muse, mutect2
- SLC39A3 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.133); catalogued as rs756204992, COSV54118796, COSV99514358; called by muse, mutect2, varscan2
- SMN2 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV101058587; called by mutect2, varscan2
- TGFBR2 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as COSV55444927, COSV99847122; called by muse, mutect2, varscan2
- TLK2 | c.691_693del p.K231del | In Frame Del (DEL) | VAF 10/77 reads (13%) | catalogued as rs779826427; called by pindel, varscan2
- TRIB2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV99331416; called by muse, mutect2, varscan2
- TRPM3 | c.4525C>A p.L1509I (on ENST00000357533 / NM_001366142.2; = p.L1364I on NM_020952.6) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100679242; called by muse, mutect2
- XIRP1 | c.5410G>A p.G1804R | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs781652700, COSV61140619; called by muse, mutect2, varscan2
- ZNF208 | c.725C>A p.S242* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV101236998, COSV101237271; called by muse, mutect2, varscan2
- FLNA | c.1159del p.Q387Kfs*33 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- MBD5 | c.3984_3986del p.L1329del | In Frame Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- PHLDA1 | c.1107_1118del p.P372_H375del | In Frame Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- ALPK3 | c.1425T>G p.T475= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV99362237; called by muse, mutect2, varscan2
- C12orf60 | c.360G>A p.T120= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as rs575360384, COSV57453796; called by muse, mutect2, varscan2
- CRACD | c.642G>A p.P214= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV51734948; called by muse, mutect2, varscan2
- PCDH11X | c.2970C>T p.S990= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV53458701; called by muse, mutect2, varscan2
- PLCG1 | c.366G>T p.L122= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV99719427; called by muse, mutect2, varscan2
- PLXNA4 | c.2647C>T p.L883= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV58170867; called by muse, mutect2, varscan2
- PTGDR | c.42G>A p.V14= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100035801; called by muse, mutect2, varscan2
- RTP5 | c.1623C>T p.Y541= | Silent (SNP) | VAF 54/295 reads (18%) | catalogued as rs1230079559, COSV58318771; called by muse, mutect2, varscan2
- VPREB1 | c.159C>T p.S53= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs947095041, COSV100164899; called by muse, mutect2, varscan2
- TBX2 | chr17:61412214 C>G | 3'Flank (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
